Gene-level copy-number profile of tumor specimen TCGA-LA-A446-01A from TCGA case TCGA-LA-A446, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.0 years (25,199 days).
Specimen TCGA-LA-A446-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.fcd9d331-8f82-46ac-9fbb-a72f67ab1c15.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LA-A446-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e50a13fe-d739-4701-931a-e8c6c498002a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 634; copy number 2: 17,182; copy number 3: 19,182; copy number 4: 16,971; copy number 5: 2,312; copy number 6: 1,200; copy number 7: 1,242; copy number 8: 117; copy number 9: 736; copy number 10: 141; copy number 12: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LA-A446-01A-21D-A256-01): tumor purity 0.41, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:98,077,000–99,309,590, 8 genes: NFU1P2, LINC01776, AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1, PLPPR4.
- chr2:154,688,296–154,858,354, 2 genes (within-gene range 0–2): AC061961.1, KCNJ3.
- chr3:88,051,944–90,030,495, 16 genes: CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3.
- chr4:133,871,246–134,010,690, 1 gene: AC079380.1.
- chr4:134,057,468–134,085,506, 1 gene: AC096763.1.
- chr9:21,409,117–26,118,408, 52 genes: IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,253 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:45,651,345–46,187,990, 1 gene, copy number 9 (within-gene range 3–9): PRKCE.
- chr2:46,003,942–52,407,917, 90 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:59,014,354–62,147,247, 61 genes, copy number 10–12 (within-gene range 3–12) (broad region; genes not listed).
- chr2:106,063,246–131,047,263, 464 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:171,317,405–178,108,339, 145 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:209,424,058–211,299,189, 19 genes, copy number 7 (within-gene range 2–7): MAP2, RNA5SP118, UNC80, SNAI1P1, RPE, KANSL1L, AC007038.1, KANSL1L-AS1, RPL6P6, AC006994.1, ACADL, Y_RNA, MYL1, LANCL1-AS1, LANCL1, CPS1, CPS1-IT1, AC012491.1, RPS27P10.
- chr3:99,817,837–111,071,553, 132 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr3:149,369,022–198,222,513, 876 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr5:710,355–2,184,820, 51 genes, copy number 9 (within-gene range 4–9): ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, AC026412.4, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA.
- chr5:19,471,296–23,689,386, 30 genes, copy number 7–8 (within-gene range 4–8): CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1.
- chr5:23,972,188–23,994,603, 3 genes, copy number 8: AC026784.1, ADH5P5, Y_RNA.
- chr5:31,053,565–32,110,932, 26 genes, copy number 8 (within-gene range 6–8): RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279.
- chr5:37,379,285–41,870,425, 62 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr5:42,423,439–45,895,970, 61 genes, copy number 7 (broad region; genes not listed).
- chr9:26,895,678–27,944,497, 20 genes, copy number 7: RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr9:28,148,211–28,149,236, 1 gene, copy number 7: AL451124.1.
- chr19:29,811,991–30,713,538, 15 genes, copy number 7 (within-gene range 4–7): CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1.
- chr19:36,510,687–40,465,764, 196 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 147. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
